Gene-level copy-number profile of tumor specimen TCGA-AP-A05D-01A from TCGA case TCGA-AP-A05D, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 67.3 years (24,597 days).
Specimen TCGA-AP-A05D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.a8954f27-46a7-4523-9ad5-c5b5bb0f4c3e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AP-A05D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b4a0c6eb-5a89-4e75-a241-78afa14a82e6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 507; copy number 2: 9,752; copy number 3: 11,891; copy number 4: 35,552; copy number 5: 840; copy number 6: 942; copy number 7: 100; copy number 8: 43; copy number 9: 17; copy number 10: 12; copy number 11: 20; copy number 12: 23; copy number 13: 8; copy number 14: 25; copy number 16: 42; copy number 18: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AP-A05D-01A-11D-A00X-01): tumor purity 0.68, ploidy 3.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 178 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,711,277–31,065,991, 13 genes, copy number 11 (within-gene range 4–11): MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420, AL137027.1, LINC01778, RN7SKP91, AL445235.1, SDC3, RN7SL371P, PUM1, AL356320.2.
- chr2:113,157,325–113,673,191, 23 genes, copy number 12: PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2.
- chr2:135,531,455–136,233,245, 15 genes, copy number 9–13 (within-gene range 4–13): R3HDM1, RNU6-512P, MIR128-1, UBXN4, LCT, Y_RNA, LCT-AS1, MCM6, MANEALP1, DARS1, DARS-AS1, AC068492.1, CXCR4, HNRNPKP2, AC112255.1.
- chr5:124,059,794–124,469,901, 6 genes, copy number 13: LINC01170, HMGB1P29, AC016556.1, AC025465.2, AC025465.4, AC025465.3.
- chr6:18,120,440–18,674,001, 12 genes, copy number 10 (within-gene range 3–10): NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1.
- chr14:68,605,396–68,736,678, 7 genes, copy number 11: AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P.
- chr17:29,560,547–29,707,090, 1 gene, copy number 14 (within-gene range 4–14): ABHD15-AS1.
- chr17:29,625,938–30,186,475, 24 genes, copy number 14 (within-gene range 1–14): SSH2, AC104564.1, RNU6-920P, AC104564.5, RPL21P123, AC023389.1, AC023389.2, SNORA70, RPL9P30, AC104982.2, AC104982.1, EFCAB5, AC104982.3, RNY4P13, AC104996.3, AC104996.1, AC104996.2, AC104984.2, NSRP1, hsa-mir-423, MIR423, MIR3184, AC104984.3, AC104984.5.
- chr17:33,013,087–34,174,964, 1 gene, copy number 18 (within-gene range 2–18): ASIC2.
- chr17:33,099,969–34,195,937, 22 genes, copy number 18: AC008133.2, AC008133.1, AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1.
- chr18:42,159,283–43,115,691, 4 genes, copy number 9 (within-gene range 4–9): LINC00907, RNA5SP454, AC084335.1, RIT2.
- chr19:29,287,011–32,073,809, 42 genes, copy number 16 (within-gene range 2–16): AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533.
- chr19:37,728,586–37,906,677, 7 genes, copy number 18: AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87.
- chr19:37,963,853–37,964,790, 1 gene, copy number 18: AC008395.1.

Autosomal genes at a single copy (total copy number 1): 507. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
